Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A73C, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A73C-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinoma, hepatocellular¹⁴⁵
817013
Site Liver
052.0
81

Female

DIAGNOSIS:

A. Liver, segments II and III, partial hepatectomy: Hepatocellular carcinoma, well differentiated (grade 1 of 4), forming a dominant, 14.5 x 10.5 x 10.0 cm mass with multiple satellite masses (see parts C, E, F). The tumor is confined to the liver. The resection margin is negative for tumor (tumor free margin, 0.5 cm). Macroscopic large vessel (venous) invasion is absent. Microscopic (small vessel) invasion is absent. No regional lymph nodes are identified. The surrounding non-neoplastic hepatic parenchyma shows no significant diagnostic abnormality (see comment).

Pathologic staging based on available surgical pathology material (AJCC 7th edition): pT3a.

Comment: The sections of the large mass present in segments II and III (part A) demonstrate a well differentiated neoplasm with bland cytology that shows loss of the normal reticulin network and dispersion of the neoplastic cells by an intercellular material suggestive of mucin. The reticulin network is preserved in the surrounding liver parenchyma. A glypican 3 stain is negative in the neoplastic cells and is noncontributory. The separately submitted wedge resections from segment VI, segment VIII, and segment IVB show smaller nodules with similar histologic features. No defined lesion is identified in the liver segment VII.

The overall features including loss of the reticulin network and the multifocality suggest, although the cytologic features are bland and well differentiated, that this represents a well differentiated hepatocellular carcinoma.

Case seen with

Additional reticulin stains will be performed on parts C and E as well as a mucicarmine stain performed on part A. These stains will be reported in an addendum, when available.

B. Gallbladder, cholecystectomy: Mild chronic cholecystitis.

C. Liver, segment VI, resection: Well differentiated hepatocellular carcinoma, forming a 1.2 x 1.1 x 0.8 cm nodule, 0.9 cm from the surgical resection margin.

D. Liver, segment VII, resection: Hepatic tissue with cautery effect. No definitive lesion is identified.

E. Liver, segment VIII, resection: Well differentiated hepatocellular carcinoma, forming a 1.0 x 1.0 x 0.9 cm nodule, 0.1 cm from the surgical resection margin.

F. Liver, segment IVB, resection: Well differentiated hepatocellular carcinoma, forming a 1.1 x 1.0 x 0.6 cm nodule, abutting the inked surgical resection margin.

Interpreted by:
Report electronically signed by
Transcribed by:

UIID:FE051CD7-9C34-4A45-934C-DD88B00C717A

[page 2 of 2]
ADDENDUM:

Reticulin stains are performed on two of the satellite nodules (blocks C1 and E1). The stains show convincing loss of the reticulin framework in both nodules, adding further support for the diagnosis of hepatocellular carcinoma with multiple satellite nodules.

Given the mucinous character of the cut tumor surface, a mucicarmin stain is performed on a representative tumor block (A2). There is a faint pink blush in the dilated sinusoids, but no intracellular mucin is identified. Some hepatocellular carcinomas can overexpress mucin-related proteins (particularly MUC1); that could possibly account for both the gross and histochemical findings.

Source: NCI Genomic Data Commons file cce9edb8-a651-4da1-a2bc-624b3e6a32e6 (TCGA-DD-A73C.FE051CD7-9C34-4A45-934C-DD8BB00C717A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).